Somatic mutation profile of tumor specimen TCGA-17-Z000-01A (aliquot TCGA-17-Z000-01A-01W-0746-08) from TCGA case TCGA-17-Z000, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z000-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22ac955c-e0d7-4b5e-9d92-5a982e84e51a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z000-11A (Solid Tissue Normal), aliquot TCGA-17-Z000-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cc4878e-349d-42a5-b272-c74c7d19cd10

The open-access MAF lists 126 somatic variants for this specimen: 102 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 21, Nonsense Mutation 11, Frame Shift Del 2, Splice Site 1, Intron 1, Frame Shift Ins 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs56030372, CM013361, COSV57566600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV55950447, COSV55950615; called by muse, mutect2
- ADAMTS12 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355654950, COSV100711178; called by muse, mutect2, varscan2
- ADAMTS12 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1412169809, COSV61278172; called by muse, mutect2, varscan2
- ADAMTS20 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV67125931; called by muse, mutect2, varscan2
- ANTXR2 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1215175695; called by muse, mutect2, varscan2
- ARID2 | c.4831C>G p.Q1611E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV57604009, COSV57609202; called by muse, mutect2, varscan2
- BSN | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs750612768; called by muse, mutect2, varscan2
- CA12 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs1344517643; called by muse, mutect2, varscan2
- CACHD1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99262077; called by muse, mutect2, varscan2
- CAVIN2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs933479342, COSV58424270; called by muse, mutect2, varscan2
- COL5A2 | c.3110C>A p.P1037Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1419168133; called by muse, mutect2, varscan2
- CPSF6 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.956); catalogued as rs867013321; called by muse, mutect2, varscan2
- CRB1 | c.3469A>T p.I1157F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1251388318; called by muse, mutect2, varscan2
- DMWD | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1338268642; called by muse, mutect2
- DNAAF5 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs754002298, COSV52416019; called by muse, mutect2, varscan2
- EIF2AK1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201849115, COSV52239853; called by muse, mutect2
- FNTA | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV56490511; called by muse, mutect2
- FOS | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1239748069, COSV100338506; called by muse, mutect2, varscan2
- FOXB1 | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68526467; called by muse, mutect2, varscan2
- FRMPD4 | c.3400C>T p.P1134S | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as rs768838591; called by muse, mutect2, varscan2
- GALNT17 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61167416; called by muse, mutect2, varscan2
- GPRC6A | c.1439A>G p.K480R | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs755104100; called by muse, mutect2, varscan2
- GRIA4 | c.1678G>A p.V560M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as rs778053723, COSV56922206; called by muse, mutect2, varscan2
- HMCN1 | c.8777G>A p.R2926Q | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.993); catalogued as rs377760099; called by muse, mutect2, varscan2
- LINS1 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV59078694; called by muse, mutect2, varscan2
- LRP2 | c.12117G>C p.M4039I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55563270; called by muse, mutect2, varscan2
- MUC17 | c.3849A>G p.I1283M | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs867046954; called by muse, mutect2, varscan2
- MYH2 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55448980; called by muse, mutect2, varscan2
- MYLK | c.5187G>T p.K1729N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100659342; called by muse, mutect2, varscan2
- NAMPT | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55994088; called by muse, mutect2, varscan2
- NAV3 | c.6925C>T p.P2309S (on ENST00000397909 / NM_001024383.2; = p.P2287S on NM_014903.6) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs769235867; called by muse, mutect2, varscan2
- NIN | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs767046757; called by muse, mutect2, varscan2
- OR14I1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.965); catalogued as rs558079121, COSV61198945; called by muse, mutect2, varscan2
- OR4P4 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1433062437; called by muse, mutect2, varscan2
- PDE10A | c.1950G>T p.Q650H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as rs1209562392; called by muse, mutect2, varscan2
- PNLIP | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs906711561; called by muse, mutect2, varscan2
- POT1 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587777472, CM144552, COSV62934929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPM1H | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.206); catalogued as rs1285286894; called by muse, mutect2, varscan2
- SCN10A | c.2566del p.A856Pfs*16 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as COSV71861147; called by mutect2, pindel, varscan2
- SMARCA4 | c.4524G>C p.K1508N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs1176688272; called by muse, mutect2, varscan2
- STT3B | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1252801725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRDN | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs1330602239, COSV62133935; called by muse, mutect2, varscan2
- TRPM1 | c.3503G>T p.R1168L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs747108363; called by muse, mutect2, varscan2
- TTLL5 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs374071149; called by muse, mutect2, varscan2
- USP47 | c.1432T>A p.S478T (on ENST00000399455 / NM_001372095.1; = p.S390T on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1488341561; called by muse, mutect2, varscan2
- ADGRF2 | c.277G>A p.A93T (on ENST00000296862 / NM_001368115.2; = p.A25T on NM_153839.7) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ATP11B | c.3521C>G p.S1174* | Nonsense Mutation (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- CACNA1S | c.1602G>T p.R534S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CAPN3 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CHD9 | c.1480_1509del p.S494_T503del | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- COL8A1 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DRC7 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EIF4E | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2
- ETS1 | c.817T>A p.S273T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FN1 | c.2380T>C p.S794P | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- FRMD1 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GFRAL | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 67/267 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GPRC6A | c.1440G>T p.K480N | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HECW1 | c.2665C>A p.Q889K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1366T>C p.Y456H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4B | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- KLRG1 | c.521C>G p.S174* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- LAMP3 | c.518C>G p.S173W | Missense Mutation (SNP) | VAF 85/226 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MAGEE2 | c.948T>A p.N316K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MPPED2 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MUC16 | c.14954C>A p.S4985* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- MUC17 | c.6499C>G p.P2167A | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NALCN | c.1330G>T p.G444* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- NLN | c.779C>G p.T260S | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NR2C2 | c.374C>T p.S125F (on ENST00000393102; = p.S144F on NM_003298.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NSD1 | c.5986T>A p.F1996I | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- OR9G4 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PAPOLA | c.1977G>C p.E659D | Missense Mutation (SNP) | VAF 197/521 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA4 | c.1595A>T p.Q532L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- POSTN | c.84_85delinsA p.L29Wfs*56 | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by pindel, varscan2*
- PRR27 | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RFX6 | c.657C>A p.S219R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RPS18 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- SLC23A3 | c.307T>G p.W103G | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLF2 | c.2994G>A p.W998* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- SPG7 | c.2056C>G p.Q686E (on ENST00000268704; = p.Q693E on NM_003119.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STAT3 | c.1945T>C p.S649P | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); called by muse, mutect2
- STMN1 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SVIL | c.4307G>A p.S1436N (on ENST00000355867 / NM_021738.3; = p.S1010N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- TAS2R40 | c.7dup p.T3Nfs*9 | Frame Shift Ins (INS) | VAF 36/177 reads (20%) | called by mutect2, pindel, varscan2
- TGFBR3 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO3 | c.1471A>T p.M491L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTBK1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBQLNL | c.100A>C p.I34L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBR2 | c.3254C>G p.S1085* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- UGT2A2 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP1 | c.557+2T>C p.X186_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- WBP4 | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR3 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- WDR3 | c.1642C>A p.L548I | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- XPO6 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZNF254 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ZNF263 | c.701A>C p.Q234P | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- ZNF623 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF813 | c.1322G>C p.C441S | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V0E1 | c.189C>G p.L63= | Silent (SNP) | VAF 49/85 reads (58%) | catalogued as rs765802797, COSV54183726; called by muse, mutect2, varscan2
- ATXN2 | c.2961G>A p.T987= (on ENST00000550104; = p.T827= on NM_002973.4) | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as rs1447177897, COSV66482668; called by muse, mutect2, varscan2
- B4GALNT3 | c.798C>T p.N266= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs781469775, COSV56750289; called by muse, mutect2, varscan2
- CCDC39 | c.363C>A p.G121= | Silent (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- CCNJ | c.75G>A p.L25= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CNOT6L | c.960G>T p.V320= (on ENST00000504123 / NM_001286790.2; = p.V315= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- GXYLT1 | c.1008G>T p.P336= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs199726389; called by muse, mutect2, varscan2
- MED23 | c.447T>A p.P149= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- NLRP5 | c.2949G>A p.Q983= | Silent (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- OR2L2 | c.60A>T p.S20= | Silent (SNP) | VAF 69/185 reads (37%) | catalogued as COSV100823386; called by muse, mutect2, varscan2
- PCDH17 | c.3450G>C p.R1150= | Silent (SNP) | VAF 67/192 reads (35%) | catalogued as COSV64971464; called by muse, mutect2, varscan2
- PTPRB | c.2949G>A p.L983= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV54249156; called by muse, mutect2, varscan2
- PXDNL | c.2835G>A p.A945= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs533962228, COSV62501917; called by muse, mutect2, varscan2
- RB1 | c.342G>T p.S114= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV57294339; called by muse, mutect2, varscan2
- RIN1 | c.2283T>A p.G761= | Silent (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- RIN3 | c.747C>T p.T249= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs758665953, COSV53653219; called by muse, mutect2, varscan2
- SHISA2 | c.807G>A p.L269= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs747649857, COSV60111391; called by muse, mutect2, varscan2
- SLC35B2 | c.309C>T p.T103= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, varscan2
- TRIL | c.231C>T p.F77= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV59867571; called by muse, mutect2
- UGT2B15 | c.966C>T p.A322= | Silent (SNP) | VAF 91/265 reads (34%) | catalogued as COSV57736721; called by muse, mutect2, varscan2
- ZPLD1 | c.894C>A p.T298= (on ENST00000466937 / NM_001329788.1; = p.T314= on NM_175056.2) | Silent (SNP) | VAF 54/148 reads (36%) | called by muse, mutect2, varscan2
- BIN1 | c.858-1464G>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs1303801044; called by muse, mutect2, varscan2
- LINC02843 | n.434C>T | RNA (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- SLITRK5 | c.-1A>G | 5'UTR (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
